Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90Z, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A90Z-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site: ④ Testis NOS C62.9
JAS 3/8/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

1-"Left testis":

- Classic seminoma;
- Greatest size of neoplasia: 9.3cm;
- Necrosis: present in approximately 10% of the neoplasia;
- Angiolymphatic invasion: present;
- Perineural invasion: not detected;
- Tunica albuginea: involved by neoplasia;
- Tunica vaginalis: uninvolved by neoplasia;
- Epididymis: involved by neoplasia;
- Rete testis: involved by neoplasia;
- Spermatic cord: uninvolved by neoplasia;
- Surgical margin (spermatic cord): uninvolved by neoplasia.

Metastasis Discrepancy		✓
Not Malignant History		
Qual/Function/Status Primary	QUALIFIED	1 DISQUALIFIED
Age to (circle):	44A	43
Collector Initials	AAA	11/5/13

Source: NCI Genomic Data Commons file 718f5f39-7495-404d-9102-88fa28630947 (TCGA-YU-A90Z-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).